Somatic mutation profile of tumor specimen 0DJE38 from CCDI case PBBURU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Pineal gland; Age at diagnosis: 4.8 years (1,765 days).
Specimen 0DJE38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82321fb0-f370-45c5-96ca-d85852407f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJE3E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7666c87-6be7-483f-ab1e-06e90059f617

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 4, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBBP7 | c.963+1G>A p.X321_splice | Splice Site (SNP) | VAF 686/1158 reads (59%) | catalogued as COSV58112660; called by muse, mutect2, varscan2
- WWC1 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 108/1726 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as rs145892564; called by muse, mutect2
- AARS1 | c.22A>C p.S8R | Missense Mutation (SNP) | VAF 138/1734 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.104); called by muse, mutect2
- ADGRG4 | c.4949A>G p.E1650G | Missense Mutation (SNP) | VAF 219/853 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 64/1216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- DGCR8 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 882/976 reads (90%) | called by muse, mutect2, varscan2
- NUAK1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 86/1444 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- SCN4B | c.150G>T p.L50= | Silent (SNP) | VAF 482/1550 reads (31%) | called by muse, mutect2, varscan2
- SDC2 | c.600T>C p.Y200= | Silent (SNP) | VAF 68/1274 reads (5%) | called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 20/206 reads (10%) | catalogued as COSV99987084; called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 20/168 reads (12%) | called by muse, varscan2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 28/334 reads (8%) | catalogued as rs1415560984; called by mutect2, varscan2
- PPP1R16A | c.705+9T>G | Intron (SNP) | VAF 73/448 reads (16%) | called by mutect2, varscan2
